Somatic mutation profile of tumor specimen C3N-02594-01 (aliquot CPT0187640030) from CPTAC case C3N-02594, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 65.4 years (23,874 days).
Specimen C3N-02594-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1141e76-b921-4f2e-9761-9cf007fc95ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02594-31 (Blood Derived Normal), aliquot CPT0187700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e9efe4e-ed71-4bbb-ae2e-83fbe95cd406

The open-access MAF lists 52 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Intron 2, 5'Flank 2, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 121/695 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 23/210 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 54/480 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 59/363 reads (16%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs374708368; called by muse, mutect2, varscan2
- AMER1 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs777453882, COSV57660865; called by muse, mutect2, varscan2
- CABIN1 | c.5047G>A p.G1683R | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs529990301, COSV99572525; called by muse, mutect2, varscan2
- CALCR | c.1259G>A p.R420H (on ENST00000649521 / NM_001164737.2; = p.R404H on NM_001742.4) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64008678; called by muse, mutect2, varscan2
- CRTAC1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.877); catalogued as rs373190208; called by muse, mutect2, varscan2
- GRAMD2A | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs779596582, COSV59032948, COSV59033257; called by muse, mutect2
- IGHV1-46 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 67/414 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.283); catalogued as rs781917710; called by muse, mutect2, varscan2
- IL4I1 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs749043676; called by muse, mutect2
- MAGEB2 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs369826731, COSV66780470; called by muse, mutect2, varscan2
- MGA | c.7474C>T p.R2492W (on ENST00000219905 / NM_001164273.1; = p.R2283W on NM_001080541.2) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1411818407, COSV54963139; called by muse, mutect2, varscan2
- OR13G1 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs1172980016; called by muse, mutect2, varscan2
- OR2T10 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as rs772598617; called by muse, mutect2, varscan2
- PDZD7 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 55/452 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766751821, COSV100931662; called by muse, mutect2, varscan2
- RIMBP2 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745374088, COSV55474609; called by muse, varscan2
- SURF6 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1019883142; called by muse, mutect2, varscan2
- TRPS1 | c.2347G>A p.E783K (on ENST00000220888 / NM_001330599.2; = p.E796K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/457 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as rs1322332596, COSV55233555, COSV55264988; called by muse, mutect2, varscan2
- UNC80 | c.4982G>A p.R1661Q | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1490619535; called by muse, mutect2
- XIRP2 | c.8954C>T p.S2985L (on ENST00000628543; = p.S3160L on NM_152381.6) | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54704762; called by muse, mutect2
- ADAMTS16 | c.3055T>A p.S1019T | Missense Mutation (SNP) | VAF 39/342 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CACNA1D | c.2516T>C p.V839A (on ENST00000350061 / NM_001128840.3; = p.V859A on NM_000720.4) | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DIP2A | c.3290C>G p.A1097G | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DISC1 | c.971A>T p.H324L | Missense Mutation (SNP) | VAF 62/411 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- EML4 | c.2543_2552delinsTG p.H848Lfs*24 | Frame Shift Del (DEL) | VAF 26/160 reads (16%) | called by pindel, varscan2*
- FAM161B | c.1076A>C p.K359T (on ENST00000651776; = p.K296T on NM_152445.3) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- MUC16 | c.26176A>T p.S8726C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- NDST4 | c.2258G>T p.R753I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- OGT | c.1062A>C p.L354F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RUNX1T1 | c.1725_1726dup p.A576Gfs*25 (on ENST00000265814 / NM_001198628.1; = p.A549Gfs*25 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 71/532 reads (13%) | called by mutect2, pindel, varscan2
- TAF3 | c.2317G>A p.V773I | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- TMEM156 | c.683T>G p.I228S | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- TNRC18 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- ZNF536 | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSS2 | c.1287G>A p.R429= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as rs778138544; called by mutect2, varscan2
- DIDO1 | c.5100T>C p.Y1700= | Silent (SNP) | VAF 8/192 reads (4%) | catalogued as rs1484673783; called by muse, mutect2
- DLGAP2 | c.792C>T p.D264= | Silent (SNP) | VAF 40/256 reads (16%) | catalogued as rs754587007, COSV101421746, COSV70096341; called by muse, mutect2, varscan2
- FAAH | c.285C>G p.A95= | Silent (SNP) | VAF 56/329 reads (17%) | catalogued as COSV54544040, COSV54544512; called by muse, mutect2, varscan2
- FANCB | c.2397G>A p.A799= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as rs746293753, COSV60761971; called by muse, mutect2, varscan2
- IRX4 | c.450G>A p.T150= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as rs200279409, COSV51471722; called by muse, mutect2, varscan2
- ISLR2 | c.219C>T p.D73= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as COSV62301723; called by muse, mutect2
- MEIOC | c.735T>G p.S245= | Silent (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- PTCH1 | c.3846G>A p.P1282= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs754412168; ClinVar: likely benign; called by muse, mutect2
- TENM3 | c.2448G>A p.P816= | Silent (SNP) | VAF 30/383 reads (8%) | catalogued as rs370217002; called by muse, mutect2
- ZSWIM8 | c.5370G>A p.A1790= (on ENST00000605216 / NM_001242487.2; = p.A1795= on NM_015037.3) | Silent (SNP) | VAF 28/195 reads (14%) | catalogued as rs371197279; called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576466 G>A | 5'Flank (SNP) | VAF 23/155 reads (15%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*1272G>A | 3'UTR (SNP) | VAF 4/26 reads (15%) | catalogued as rs1181117614; called by muse, mutect2
- GMPR2 | c.857+33T>C | Intron (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- NT5C3A | c.139-2742C>T | Intron (SNP) | VAF 21/170 reads (12%) | catalogued as rs757525881; called by muse, mutect2, varscan2
- SLC25A13 | chr7:96322121 G>T | 5'Flank (SNP) | VAF 24/146 reads (16%) | catalogued as rs1027911138; called by muse, varscan2
